Somatic mutation profile of tumor specimen TCGA-77-7139-01A (aliquot TCGA-77-7139-01A-11D-2042-08) from TCGA case TCGA-77-7139, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.5 years (20,632 days).
Specimen TCGA-77-7139-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc17ad6d-f04a-4d4d-a640-54bec95b6aa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-7139-10A (Blood Derived Normal), aliquot TCGA-77-7139-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73d42315-309f-412e-8f64-9da63f83c926

The open-access MAF lists 208 somatic variants for this specimen: 151 protein-altering or splice-affecting, 49 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 49, Nonsense Mutation 15, Splice Site 4, Intron 3, RNA 3, Frame Shift Del 2, 5'UTR 1, Splice Region 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- POFUT1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as rs398123038, CM134922, COSV100998394; ClinVar: pathogenic; called by muse, mutect2
- AASS | c.1956G>T p.W652C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100741857; called by muse, mutect2, varscan2
- ABCA13 | c.5402C>T p.T1801I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV101330135; called by muse, mutect2, varscan2
- ABCC6 | c.2989C>A p.L997I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.178); catalogued as COSV99229316; called by muse, mutect2, varscan2
- ACSF2 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs917299412, COSV99366277; called by muse, mutect2, varscan2
- ADAM19 | c.1028T>C p.M343T | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs777587974, COSV99978011; called by muse, mutect2, varscan2
- ADAM2 | c.1496C>T p.T499I | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370916151; called by muse, mutect2, varscan2
- ADAMTS16 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV99942268; called by muse, mutect2, varscan2
- ADGRG4 | c.8002G>A p.V2668I | Missense Mutation (SNP) | VAF 66/78 reads (85%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV99796270; called by muse, mutect2, varscan2
- AGO3 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 98/123 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as rs761675753, COSV99869178; called by muse, mutect2, varscan2
- AK9 | c.2908A>G p.K970E | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100394119; called by muse, mutect2, varscan2
- AKAP3 | c.2387A>T p.D796V | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99962484; called by muse, mutect2, varscan2
- AMY2A | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 85/112 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV101340661; called by muse, mutect2, varscan2
- ANKFN1 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 95/217 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100593941; called by muse, mutect2, varscan2
- ARHGEF11 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100810363; called by muse, mutect2, varscan2
- ATP6V0D2 | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.61); catalogued as COSV99571980; called by muse, mutect2, varscan2
- BAIAP2L2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60201305; called by muse, mutect2, varscan2
- BHLHE40 | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.603); catalogued as rs367853904, COSV99848239, COSV99848363; called by muse, mutect2, varscan2
- BRINP2 | c.1927C>T p.H643Y | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100838253; called by muse, mutect2
- CARD8 | c.848G>T p.R283L (on ENST00000651546 / NM_001184900.3; = p.R233L on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100751189; called by muse, mutect2, varscan2
- CCKBR | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as rs746523028, COSV58102335, COSV58105140; called by muse, mutect2, varscan2
- CD163L1 | c.3329C>T p.S1110F | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100550512; called by muse, mutect2, varscan2
- CD177 | c.1121C>A p.A374D | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV100946032; called by muse, mutect2, varscan2
- CD22 | c.1813C>G p.Q605E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV99323589; called by muse, mutect2, varscan2
- CD300LG | c.845C>A p.T282K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.247); catalogued as COSV99517571; called by muse, mutect2, varscan2
- CDC37 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs937318355, COSV99705849; called by muse, mutect2, varscan2
- CDH10 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 41/100 reads (41%) | catalogued as COSV100052575; called by muse, mutect2, varscan2
- CEP131 | c.2729A>T p.D910V (on ENST00000269392 / NM_001319228.2; = p.D907V on NM_014984.4) | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99488788; called by muse, mutect2, varscan2
- CHRNA1 | c.190-1G>A p.X64_splice | Splice Site (SNP) | VAF 33/61 reads (54%) | catalogued as rs1419004619, COSV53682152, COSV99650605; called by muse, mutect2, varscan2
- CSMD3 | c.7441C>T p.L2481F (on ENST00000297405 / NM_001363185.1; = p.L2377F on NM_052900.3) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV52214163, COSV99842927; called by muse, mutect2, varscan2
- CSMD3 | c.4397A>G p.H1466R (on ENST00000297405 / NM_001363185.1; = p.H1362R on NM_052900.3) | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs776732607, COSV99842931; called by muse, mutect2, varscan2
- CTSO | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV101467872; called by muse, mutect2, varscan2
- CWF19L2 | c.1028C>G p.S343C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as COSV99979574; called by muse, mutect2, varscan2
- CYP2C18 | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99608793; called by muse, mutect2, varscan2
- CYP8B1 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.374); catalogued as COSV100296240; called by muse, mutect2, varscan2
- DCLRE1A | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 64/107 reads (60%) | catalogued as rs1236108254, COSV100800452; called by muse, mutect2, varscan2
- DISP1 | c.3367G>T p.A1123S | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV52658104, COSV99451342; called by muse, mutect2, varscan2
- DLL1 | c.992A>G p.E331G | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100816161; called by muse, mutect2, varscan2
- DPPA4 | c.883A>C p.K295Q | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV100169598; called by muse, mutect2, varscan2
- DPYSL5 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99982637; called by muse, mutect2, varscan2
- DROSHA | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV100757761; called by muse, mutect2
- EEF1AKMT1 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 35/42 reads (83%) | catalogued as COSV66964469; called by muse, mutect2, varscan2
- EFEMP1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.131); catalogued as COSV100816936; called by muse, varscan2
- EGFLAM | c.193A>T p.I65F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as COSV100472854; called by muse, mutect2
- ENPP2 | c.1319G>A p.R440K (on ENST00000075322 / NM_001040092.3; = p.R492K on NM_006209.5) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50012206, COSV99309026; called by muse, mutect2, varscan2
- ERBB4 | c.3778C>A p.Q1260K | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV100726693; called by muse, mutect2, varscan2
- EXOC2 | c.1932+1G>T p.X644_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100034020; called by muse, mutect2, varscan2
- FLNC | c.2048T>A p.I683N | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV100368515; called by muse, varscan2
- FLNC | c.2050G>C p.V684L | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.203); catalogued as rs769221710, COSV100368520; called by muse, varscan2
- FLRT2 | c.1371G>T p.M457I | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100420783; called by muse, varscan2
- FMN1 | c.3562G>T p.G1188* (on ENST00000616417 / NM_001277313.2; = p.G965* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 23/139 reads (17%) | catalogued as COSV100569173; called by muse, mutect2
- FRMPD1 | c.1988A>G p.Q663R | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); catalogued as COSV100899604; called by muse, mutect2, varscan2
- FRY | c.4294G>T p.G1432W | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0.056); catalogued as COSV66581852; called by muse, mutect2, varscan2
- FRY | c.4295G>T p.G1432V | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.51); PolyPhen benign (0.243); catalogued as COSV100969725; called by muse, mutect2, varscan2
- FSHR | c.1733T>C p.I578T | Missense Mutation (SNP) | VAF 432/457 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100437725; called by muse, mutect2, varscan2
- GDF15 | c.845T>C p.M282T | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV99416242; called by muse, mutect2, varscan2
- GLT1D1 | c.667G>T p.G223W (on ENST00000442111 / NM_001366889.1; = p.G143W on NM_144669.3) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV99897193; called by muse, mutect2, varscan2
- GPC5 | c.1253G>A p.C418Y | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100995129; called by muse, mutect2, varscan2
- GPR68 | c.517T>C p.F173L | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99473546; called by muse, mutect2, varscan2
- GTF3C1 | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100649622; called by mutect2, varscan2
- HAO1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV101113280; called by muse, mutect2
- HDC | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 76/127 reads (60%) | catalogued as rs750405599, COSV51068254; called by muse, mutect2, varscan2
- HOXA3 | c.957C>A p.C319* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100415608; called by muse, mutect2, varscan2
- IL7R | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV57408816; called by muse, mutect2, varscan2
- INSC | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as rs761410512, COSV101089515; called by muse, mutect2, varscan2
- KALRN | c.6597G>T p.E2199D (on ENST00000360013 / NM_001024660.4; = p.E502D on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.253); catalogued as COSV99362646; called by muse, mutect2, varscan2
- KCNJ3 | c.278T>A p.V93E | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99716271; called by muse, mutect2, varscan2
- KCNQ1 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV50136819, COSV99327886, COSV99327894; called by muse, mutect2, varscan2
- KCNQ5 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59678539; called by muse, mutect2, varscan2
- KDM6A | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV65048890; called by muse, mutect2, varscan2
- KIF21A | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778195029, COSV100735570; called by muse, mutect2, varscan2
- KIF2B | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 96/257 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV99275915; called by muse, mutect2, varscan2
- KRT40 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100898884; called by muse, mutect2
- KRT79 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as rs1443867087, COSV100398517; called by muse, mutect2, varscan2
- LAMB2 | c.4911G>T p.Q1637H | Missense Mutation (SNP) | VAF 64/89 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100026403; called by muse, mutect2, varscan2
- LAMC3 | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV100736050; called by muse, mutect2, varscan2
- LATS1 | c.2011G>A p.V671I | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV99486460; called by muse, mutect2, varscan2
- LIG3 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV99252971; called by muse, mutect2, varscan2
- LMNTD1 | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV99280156; called by mutect2, varscan2
- LRRC37A2 | c.4070G>T p.G1357V | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as COSV100238805; called by muse, mutect2, varscan2
- LRRC4C | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs375080235, COSV99539146; called by muse, mutect2, varscan2
- LTV1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as rs747127841, COSV62536324, COSV62536759; called by muse, mutect2, varscan2
- MAGEC2 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 99/120 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV99909808; called by muse, mutect2, varscan2
- MAP3K19 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100209004; called by muse, mutect2, varscan2
- MDN1 | c.4006C>G p.L1336V | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV101021659; called by muse, mutect2, varscan2
- MIB2 | c.1172A>G p.Q391R | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1307383898; called by muse, mutect2, varscan2
- MROH8 | c.1747T>A p.Y583N | Missense Mutation (SNP) | VAF 97/275 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54126115, COSV99457727; called by muse, mutect2, varscan2
- MUC16 | c.11479C>A p.Q3827K | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs779852586, COSV101200694; called by muse, mutect2, varscan2
- MYO3B | c.3928T>C p.S1310P | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.143); catalogued as COSV100511234; called by muse, mutect2, varscan2
- NDST4 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as COSV99997400; called by muse, mutect2, varscan2
- NDST4 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs751817832, COSV99997402; called by muse, mutect2, varscan2
- NDUFAF7 | c.1289C>A p.S430Y | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.547); catalogued as rs1440268543, COSV99135721; called by muse, mutect2, varscan2
- NLRP10 | c.564G>T p.L188F | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100149889; called by muse, mutect2, varscan2
- NLRP8 | c.1443G>T p.Q481H | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV99405741; called by muse, mutect2, varscan2
- NOCT | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as rs1417223241, COSV99763927; called by muse, mutect2, varscan2
- NOTCH1 | c.5155G>T p.E1719* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | catalogued as COSV99490401; called by muse, mutect2, varscan2
- OR10Q1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.191); catalogued as rs1306805450, COSV57469953; called by muse, mutect2, varscan2
- OR52A5 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145415920, COSV56616491; called by muse, mutect2, varscan2
- OR5A2 | c.93A>T p.L31F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100119820; called by muse, mutect2, varscan2
- OR5AK2 | c.257C>G p.T86R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV100476114; called by muse, mutect2, varscan2
- OR6C74 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV100667819; called by muse, mutect2, varscan2
- PEG10 | c.128C>T p.T43I (on ENST00000482108 / NM_001040152.2; = p.T77I on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.044); catalogued as COSV101509935; called by muse, mutect2, varscan2
- PKHD1L1 | c.10870A>T p.T3624S | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.082); catalogued as COSV101006628; called by muse, mutect2, varscan2
- PNPLA7 | c.367A>C p.T123P | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV99481172; called by muse, mutect2, varscan2
- PPARGC1B | c.3017A>T p.Y1006F | Missense Mutation (SNP) | VAF 89/114 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV100495001; called by muse, mutect2, varscan2
- PRKCG | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV99669378; called by muse, mutect2, varscan2
- PRKCQ | c.913A>G p.R305G | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs745477282, COSV99577533; called by muse, mutect2, varscan2
- PROS1 | c.77-1G>A p.X26_splice | Splice Site (SNP) | VAF 16/70 reads (23%) | catalogued as rs759677822, CS991489, COSV100820349; called by muse, mutect2, varscan2
- PTCHD4 | c.2177T>C p.I726T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs146541117; called by muse, mutect2, varscan2
- RBM15 | c.2693A>T p.K898M | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100873482; called by muse, mutect2, varscan2
- ROS1 | c.5443T>G p.C1815G | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100877533; called by muse, mutect2, varscan2
- SCN10A | c.4203C>A p.F1401L | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101479485; called by muse, mutect2, varscan2
- SGCZ | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748629706, COSV101171105; called by muse, mutect2, varscan2
- SLC12A2 | c.3410A>T p.N1137I | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99321416; called by muse, mutect2, varscan2
- SLC16A7 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs766674596, COSV53892176; called by muse, mutect2, varscan2
- SLC1A2 | c.156T>C p.F52= | Splice Region (SNP) | VAF 51/69 reads (74%) | catalogued as COSV53526620; called by muse, mutect2, varscan2
- SLC6A18 | c.1532G>C p.R511P | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV99722560; called by muse, mutect2, varscan2
- SLN | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.014); catalogued as rs763412767, COSV100019417; called by muse, mutect2, varscan2
- SMARCA4 | c.3502del p.A1168Qfs*4 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as COSV100758179; called by mutect2, pindel, varscan2
- SPATA31D1 | c.3568T>C p.S1190P | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV100782966; called by muse, mutect2, varscan2
- SRRT | c.2366A>G p.H789R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.41); catalogued as COSV99574395; called by muse, mutect2, varscan2
- SSRP1 | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV99555071; called by muse, mutect2, varscan2
- STAM | c.1601A>G p.Y534C | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101098271; called by muse, mutect2, varscan2
- STN1 | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV99830293; called by muse, mutect2, varscan2
- SULF1 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 72/119 reads (61%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.577); catalogued as rs201100928, COSV99036132, COSV99483921; called by muse, mutect2, varscan2
- SYMPK | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs1348104274, COSV55609973, COSV99841955; called by muse, mutect2, varscan2
- SYNE1 | c.22096G>T p.A7366S (on ENST00000367255 / NM_182961.4; = p.A7295S on NM_033071.3) | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV55032268, COSV99573971; called by muse, mutect2
- TMEM106B | c.542T>A p.L181* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | catalogued as COSV101188858; called by muse, mutect2, varscan2
- TMEM200A | c.1015C>A p.Q339K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51658450, COSV51659876; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4258G>T p.E1420* | Nonsense Mutation (SNP) | VAF 72/206 reads (35%) | catalogued as COSV100836175; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3473C>T p.S1158L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs150046410; called by muse, mutect2, varscan2
- TNRC6A | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV100170361; called by muse, mutect2, varscan2
- TP53 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 136/172 reads (79%) | catalogued as CM107390, COSV52689258; called by muse, mutect2, varscan2
- TPO | c.2461T>A p.F821I | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100221768; called by muse, mutect2, varscan2
- TRIM48 | c.556-1G>T p.X186_splice | Splice Site (SNP) | VAF 17/49 reads (35%) | catalogued as COSV101338337, COSV70162807; called by muse, mutect2, varscan2
- TRIM58 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as rs1325984486, COSV100825226; called by muse, mutect2, varscan2
- TRIO | c.3740G>A p.G1247E | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100710749; called by muse, mutect2, varscan2
- TULP4 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV100893694; called by muse, varscan2
- VPS8 | c.3067C>T p.Q1023* (on ENST00000625842 / NM_001349294.1; = p.Q1021* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99803305; called by muse, mutect2, varscan2
- WDR17 | c.2260G>A p.G754S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1195152673, COSV99708050; called by muse, mutect2, varscan2
- YPEL5 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99745299; called by muse, mutect2, varscan2
- ZIM3 | c.483A>T p.K161N | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.248); catalogued as COSV99518433; called by muse, mutect2, varscan2
- ZNF112 | c.67G>A p.G23R (on ENST00000337401 / NM_001083335.2; = p.G17R on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.416); catalogued as COSV100496133; called by muse, mutect2, varscan2
- ZNF292 | c.4321A>G p.T1441A | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1484693655, COSV100370877; called by muse, mutect2, varscan2
- ZNF33A | c.1806T>A p.H602Q (on ENST00000458705 / NM_006974.3; = p.H603Q on NM_006954.2) | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100276091; called by muse, mutect2, varscan2
- ZNF362 | c.505A>G p.S169G | Missense Mutation (SNP) | VAF 57/78 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65031601; called by muse, mutect2, varscan2
- ZNF506 | c.1187C>A p.P396Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101475652, COSV71354276; called by muse, mutect2, varscan2
- ZNF611 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100160505; called by muse, mutect2, varscan2
- MMP14 | c.1561_1572del p.E521_V524del | In Frame Del (DEL) | VAF 13/34 reads (38%) | called by mutect2, pindel
- SPANXB1 | c.39C>G p.S13R | Missense Mutation (SNP) | VAF 72/463 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF830 | c.347del p.A116Gfs*23 | Frame Shift Del (DEL) | VAF 47/142 reads (33%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2910C>T p.C970= | Silent (SNP) | VAF 16/19 reads (84%) | catalogued as COSV99672138; called by muse, mutect2, varscan2
- BCL9L | c.2802G>T p.S934= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs776947550, COSV99419842; called by muse, mutect2, varscan2
- BFSP1 | c.1330C>T p.L444= | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as COSV100925421; called by muse, mutect2, varscan2
- BMP7 | c.489C>T p.I163= | Silent (SNP) | VAF 70/210 reads (33%) | catalogued as COSV101216165; called by muse, mutect2, varscan2
- BRINP1 | c.1408C>A p.R470= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99775127; called by muse, mutect2, varscan2
- CALHM2 | c.159C>T p.N53= | Silent (SNP) | VAF 45/75 reads (60%) | catalogued as COSV99588758; called by muse, mutect2, varscan2
- CCDC62 | c.1263C>T p.P421= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs542590389, COSV99457532; called by muse, mutect2, varscan2
- CD177 | c.1122C>A p.A374= | Silent (SNP) | VAF 48/105 reads (46%) | catalogued as COSV100946034; called by muse, mutect2, varscan2
- CFLAR | c.1174C>T p.L392= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100009724; called by muse, mutect2, varscan2
- CPA3 | c.903C>A p.I301= | Silent (SNP) | VAF 34/142 reads (24%) | catalogued as COSV56047231, COSV99936372; called by muse, mutect2, varscan2
- CYFIP2 | c.1458C>T p.F486= | Silent (SNP) | VAF 76/104 reads (73%) | catalogued as rs563909737, COSV100557364; called by muse, mutect2, varscan2
- DLL1 | c.993G>A p.E331= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1439065912, COSV100816159; called by muse, mutect2, varscan2
- FGF6 | c.246C>T p.I82= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV57403278; called by muse, mutect2, varscan2
- FLNC | c.2049C>T p.I683= | Silent (SNP) | VAF 42/243 reads (17%) | catalogued as rs767801521, COSV100368518; called by muse, varscan2
- GLIS3 | c.378T>C p.S126= | Silent (SNP) | VAF 115/142 reads (81%) | catalogued as COSV100174546; called by muse, mutect2, varscan2
- HMCN1 | c.16783C>A p.R5595= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV54884056, COSV99633533; called by muse, mutect2, varscan2
- HOXB9 | c.270C>G p.A90= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100239574; called by muse, mutect2
- HSF2 | c.1044G>A p.L348= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV63773866; called by muse, mutect2, varscan2
- HUWE1 | c.5286C>T p.C1762= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs782727155, COSV53356228; called by muse, mutect2, varscan2
- IGKV1D-16 | c.207G>C p.L69= | Silent (SNP) | VAF 125/149 reads (84%) | catalogued as rs1343338302; called by muse, mutect2, varscan2
- KRT8 | c.948G>T p.R316= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV99510253; called by muse, mutect2, varscan2
- MS4A7 | c.402C>T p.L134= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100279703; called by muse, mutect2, varscan2
- MTUS2 | c.603C>T p.D201= | Silent (SNP) | VAF 44/53 reads (83%) | catalogued as rs764783443, COSV70913256; called by muse, mutect2, varscan2
- NLRP5 | c.1299C>T p.S433= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs199735091, COSV101173823; called by muse, mutect2, varscan2
- NOTCH1 | c.2379C>T p.N793= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs200565505, COSV99490403; called by muse, mutect2, varscan2
- OR10R2 | c.297C>A p.P99= | Silent (SNP) | VAF 83/234 reads (35%) | catalogued as COSV100936823; called by muse, mutect2, varscan2
- OR2C3 | c.831G>T p.L277= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV100825761; called by muse, mutect2, varscan2
- OR2W3 | c.120A>T p.V40= | Silent (SNP) | VAF 99/238 reads (42%) | catalogued as COSV100831654, COSV100831783; called by muse, mutect2, varscan2
- PCDHB13 | c.1155C>T p.S385= | Silent (SNP) | VAF 58/80 reads (73%) | catalogued as COSV99507608; called by muse, mutect2, varscan2
- PDZRN4 | c.1872T>C p.C624= (on ENST00000402685 / NM_001164595.2; = p.C366= on NM_013377.4) | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV100115174; called by muse, mutect2, varscan2
- PGR | c.1116C>T p.D372= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99678864; called by muse, mutect2, varscan2
- PIK3CA | c.1974G>A p.L658= | Silent (SNP) | VAF 104/289 reads (36%) | catalogued as COSV55971959, COSV99841668; called by muse, mutect2, varscan2
- PITRM1 | c.2182C>A p.R728= | Silent (SNP) | VAF 70/155 reads (45%) | catalogued as rs570447323, COSV99829394, COSV99829398; called by muse, mutect2, varscan2
- PLIN4 | c.3960C>A p.R1320= (on ENST00000301286; = p.R1335= on NM_001367868.2) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100012382; called by muse, mutect2, varscan2
- PPP1R3A | c.2682G>C p.S894= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV52893811, COSV99493770; called by muse, mutect2, varscan2
- PPP2R5A | c.1335A>G p.K445= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV99801423; called by muse, mutect2, varscan2
- PYROXD1 | c.804T>G p.L268= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as COSV99556685; called by muse, mutect2, varscan2
- SEMA5B | c.216C>A p.P72= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99532777; called by muse, mutect2, varscan2
- SNRNP200 | c.2229A>G p.L743= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV100107920; called by muse, mutect2, varscan2
- TAAR1 | c.414G>A p.L138= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99257703; called by muse, mutect2, varscan2
- THSD7A | c.1497T>A p.P499= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV101448832; called by muse, mutect2, varscan2
- TLR4 | c.1440C>T p.G480= (on ENST00000355622 / NM_138554.5; = p.G440= on NM_003266.4) | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100842828; called by muse, mutect2, varscan2
- TMEM245 | c.2118T>C p.A706= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV101002433; called by muse, mutect2, varscan2
- TTN | c.82674C>A p.V27558= (on ENST00000591111; = p.V20134= on NM_003319.4) | Silent (SNP) | VAF 107/386 reads (28%) | catalogued as COSV100623545; called by muse, mutect2, varscan2
- TTN | c.81582A>G p.S27194= (on ENST00000591111; = p.S19770= on NM_003319.4) | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV100623547; called by muse, mutect2, varscan2
- USH2A | c.5544C>T p.N1848= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as COSV100239668; called by muse, mutect2, varscan2
- USP29 | c.1470G>A p.K490= | Silent (SNP) | VAF 52/85 reads (61%) | catalogued as rs769171367, COSV99518429; called by muse, mutect2, varscan2
- ZNF417 | c.1518G>T p.A506= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100364359, COSV100364364; called by muse, mutect2
- ZNF808 | c.2661G>C p.R887= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100708123, COSV63120683; called by muse, mutect2, varscan2
- AL133467.6 | n.77C>A | RNA (SNP) | VAF 22/30 reads (73%) | called by muse, mutect2, varscan2
- C15orf54 | n.460C>T | RNA (SNP) | VAF 54/313 reads (17%) | called by muse, mutect2, varscan2
- C6orf58 | c.-2C>A | 5'UTR (SNP) | VAF 42/73 reads (58%) | catalogued as COSV100315013; called by muse, mutect2, varscan2
- DET1 | c.-10-4605A>T | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99183887; called by muse, mutect2, varscan2
- ESRRB | c.1296+439G>C | Intron (SNP) | VAF 12/22 reads (55%) | catalogued as COSV99835607; called by muse, mutect2, varscan2
- TTN | c.10360+3037del | Intron (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- UBTFL2 | n.803A>T | RNA (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- ZNF99 | c.*186C>A | 3'UTR (SNP) | VAF 43/95 reads (45%) | catalogued as COSV101233910; called by muse, mutect2, varscan2
